FM case AD797 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Other and ill-defined sites.
https://portal.gdc.cancer.gov/cases/18604d55-1905-4961-8234-9c5512bbccca

Male, 43.8 years: Neuroendocrine carcinoma, NOS (ICD-O-3 8246/3) of the head, face or neck; specimen biopsied or resected from the liver. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Tumor.
